Somatic mutation profile of tumor specimen 0D8BV9 from CCDI case PBBHGT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 7.7 years (2,799 days).
Specimen 0D8BV9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c936554-9282-4260-8e20-dbc78696f0de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8BVB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e89358eb-1eb6-4a1f-92f3-9f61d8deb2f0

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Translation Start Site 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG5 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 53/987 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs373794853; called by muse, mutect2
- MFAP2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 284/969 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- THADA | c.2948-1G>T p.X983_splice | Splice Site (SNP) | VAF 90/306 reads (29%) | called by muse, mutect2, varscan2
- UPF1 | c.2141G>A p.R714Q (on ENST00000599848 / NM_001297549.2; = p.R703Q on NM_002911.4) | Missense Mutation (SNP) | VAF 321/655 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF493 | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.024); called by muse, mutect2
- ZRANB3 | c.2308G>T p.E770* | Nonsense Mutation (SNP) | VAF 266/447 reads (60%) | called by mutect2, varscan2
- B3GALT4 | c.882G>C p.V294= | Silent (SNP) | VAF 149/547 reads (27%) | called by muse, mutect2, varscan2
- CEP128 | c.49T>C p.L17= | Silent (SNP) | VAF 76/668 reads (11%) | catalogued as rs536338249; called by muse, mutect2, varscan2
